Gene-level copy-number profile of tumor specimen TCGA-02-0269-01B from TCGA case TCGA-02-0269, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 69.0 years (25,194 days).
Specimen TCGA-02-0269-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.46d14376-fe70-4901-a2c5-943facb4574b.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,272 have no estimate.
https://portal.gdc.cancer.gov/files/3575df64-4931-4608-be4b-f4ae5d7c4e61

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,492; copy number 2: 41,018; copy number 3: 11,841.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-02-0269-01): tumor purity 0.93, ploidy 2.13, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
